Somatic mutation profile of tumor specimen ALCH-B3JK-TTP1-A (aliquot ALCH-B3JK-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3JK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.3 years (22,385 days).
Specimen ALCH-B3JK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4241e61-bb87-4c3f-923e-db30008ae43a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3JK-NB1-A (Blood Derived Normal), aliquot ALCH-B3JK-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b32bf11-770f-48f8-af3d-e5476449325b

The open-access MAF lists 95 somatic variants for this specimen: 66 protein-altering or splice-affecting, 16 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 16, Intron 7, Nonsense Mutation 3, RNA 3, Frame Shift Del 3, In Frame Del 2, 3'UTR 2, Splice Site 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 256/785 reads (33%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- AKAP6 | c.4858G>A p.V1620M | Missense Mutation (SNP) | VAF 44/711 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.271); catalogued as rs756942987, COSV99805395; called by muse, mutect2
- BOC | c.2516G>A p.R839Q | Missense Mutation (SNP) | VAF 60/451 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.206); catalogued as rs201334578; called by muse, mutect2, varscan2
- CYB5R4 | c.61G>T p.G21W | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs1330901281; called by muse, mutect2, varscan2
- ERCC4 | c.680C>T p.T227I | Missense Mutation (SNP) | VAF 66/702 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.137); catalogued as COSV61312501; called by muse, mutect2
- EYS | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.333); catalogued as COSV61002551; called by muse, mutect2
- F5 | c.2108T>A p.V703D | Missense Mutation (SNP) | VAF 177/1509 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.079); catalogued as COSV63120286; called by muse, mutect2, varscan2
- F9 | c.1182G>A p.M394I | Missense Mutation (SNP) | VAF 76/525 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1388797589, CM940677; called by muse, mutect2, varscan2
- FLI1 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 31/316 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760569858, COSV55644737; called by muse, mutect2, varscan2
- FNBP4 | c.1856C>A p.S619* | Nonsense Mutation (SNP) | VAF 55/320 reads (17%) | catalogued as COSV55451906, COSV99771337, COSV99771900; called by muse, mutect2, varscan2
- FTO | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 401/1384 reads (29%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1271268742; called by muse, mutect2, varscan2
- GOLGA7B | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs1564868055; called by muse, mutect2
- IL18R1 | c.1088C>T p.T363M | Missense Mutation (SNP) | VAF 60/437 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs187081342; called by muse, mutect2, varscan2
- ITGA8 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 102/476 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.109); catalogued as COSV100959921; called by muse, mutect2, varscan2
- MAP3K15 | c.2252A>C p.K751T | Missense Mutation (SNP) | VAF 22/412 reads (5%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.646); catalogued as COSV58827337; called by muse, mutect2
- MGAM | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 59/371 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); catalogued as rs781873643, COSV72074463; called by muse, mutect2, varscan2
- MNDA | c.886C>G p.P296A | Missense Mutation (SNP) | VAF 71/489 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV63741943; called by muse, mutect2, varscan2
- NYNRIN | c.5447G>A p.R1816H | Missense Mutation (SNP) | VAF 208/479 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs775804688, COSV66844047; called by muse, mutect2, varscan2
- OR4K17 | c.671C>G p.T224S | Missense Mutation (SNP) | VAF 215/663 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.277); catalogued as COSV100210616; called by muse, mutect2, varscan2
- PPA1 | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV64683795; called by muse, mutect2, varscan2
- RNH1 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767577716; called by muse, mutect2, varscan2
- RP1L1 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.166); catalogued as rs777820137, COSV61444112; called by muse, mutect2, varscan2
- RTTN | c.5663A>G p.N1888S | Missense Mutation (SNP) | VAF 64/850 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769609021; called by muse, mutect2
- SEMA4C | c.1228C>A p.R410S | Missense Mutation (SNP) | VAF 43/341 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV59690854; called by muse, mutect2, varscan2
- TUSC3 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 150/1348 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.455); catalogued as rs777646780, COSV65879530; called by muse, mutect2, varscan2
- VPS52 | c.1591C>T p.R531W | Missense Mutation (SNP) | VAF 31/423 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs1252573623; called by muse, mutect2
- ZIC5 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1361595536, COSV99032033; called by muse, mutect2
- ZNF572 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 57/626 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV60001143, COSV60002420; called by muse, mutect2
- ACP1 | c.339A>C p.K113N | Missense Mutation (SNP) | VAF 106/324 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ACTB | c.1058A>T p.Q353L | Missense Mutation (SNP) | VAF 167/810 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- BARHL1 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C5 | c.2195G>T p.C732F | Missense Mutation (SNP) | VAF 33/346 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CACNA1F | c.3672C>G p.I1224M | Missense Mutation (SNP) | VAF 61/776 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); called by muse, mutect2
- COPB2 | c.374T>C p.L125P | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CSNK1E | c.612G>A p.M204I | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- DNAH11 | c.10784A>C p.E3595A | Missense Mutation (SNP) | VAF 74/682 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2
- DSPP | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 81/651 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- DST | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 244/904 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- FAM160B1 | c.1841G>A p.W614* | Nonsense Mutation (SNP) | VAF 145/693 reads (21%) | called by muse, mutect2, varscan2
- FCF1 | c.342del p.Q115Rfs*7 | Frame Shift Del (DEL) | VAF 48/282 reads (17%) | called by mutect2, pindel, varscan2
- FGL1 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 54/287 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- HIVEP1 | c.3589G>C p.A1197P | Missense Mutation (SNP) | VAF 283/669 reads (42%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- HSPA12A | c.1537A>C p.T513P | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- HSPA12B | c.2002del p.A668Pfs*51 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- IGLV1-40 | c.137C>G p.S46C | Missense Mutation (SNP) | VAF 60/452 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- KRT6B | c.974A>G p.N325S | Missense Mutation (SNP) | VAF 125/1130 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- KRTCAP3 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- MDM1 | c.2035G>C p.E679Q | Missense Mutation (SNP) | VAF 50/670 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.154); called by muse, mutect2
- MICAL2 | c.5494_5501del p.K1832Afs*11 | Frame Shift Del (DEL) | VAF 49/443 reads (11%) | called by mutect2, pindel
- MXRA5 | c.7326C>G p.I2442M | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NDC1 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 38/327 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- NDUFA9 | c.265T>C p.Y89H | Missense Mutation (SNP) | VAF 61/444 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- OR5T1 | c.493A>C p.I165L | Missense Mutation (SNP) | VAF 100/400 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- OR8K1 | c.900C>A p.N300K | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- PKDCC | c.1357_1362del p.C453_R454del | In Frame Del (DEL) | VAF 62/404 reads (15%) | called by mutect2, pindel, varscan2
- PLPPR4 | c.1828A>T p.K610* | Nonsense Mutation (SNP) | VAF 59/478 reads (12%) | called by muse, mutect2, varscan2
- POLA1 | c.2992G>T p.V998F | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- RASA1 | c.1611-2A>G p.X537_splice | Splice Site (SNP) | VAF 90/347 reads (26%) | called by muse, mutect2, varscan2
- ROBO1 | c.4103G>A p.G1368E | Missense Mutation (SNP) | VAF 35/327 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- SLF1 | c.401G>C p.R134T | Missense Mutation (SNP) | VAF 54/353 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- SMC1A | c.1411G>A p.D471N | Missense Mutation (SNP) | VAF 51/859 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.415); called by muse, mutect2
- SNX31 | c.145A>T p.R49W | Missense Mutation (SNP) | VAF 68/280 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- SYNE2 | c.10914T>G p.I3638M | Missense Mutation (SNP) | VAF 86/836 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.123); called by muse, mutect2
- TP53 | c.484_486del p.I162del | In Frame Del (DEL) | VAF 59/231 reads (26%) | called by mutect2, pindel, varscan2
- WWC1 | c.2855T>G p.L952R | Missense Mutation (SNP) | VAF 45/259 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- ZNF681 | c.725C>G p.T242S | Missense Mutation (SNP) | VAF 33/288 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CCIN | c.363C>T p.N121= | Silent (SNP) | VAF 50/418 reads (12%) | catalogued as rs372099901; called by muse, mutect2, varscan2
- CCSER1 | c.1740A>G p.K580= | Silent (SNP) | VAF 99/710 reads (14%) | called by muse, mutect2, varscan2
- CNTN4 | c.174T>A p.P58= | Silent (SNP) | VAF 62/601 reads (10%) | called by muse, mutect2, varscan2
- EPHA8 | c.1251C>A p.G417= | Silent (SNP) | VAF 9/200 reads (5%) | catalogued as rs1388373713, COSV51278145; called by muse, mutect2
- MPO | c.270C>T p.S90= | Silent (SNP) | VAF 21/169 reads (12%) | catalogued as rs963340586; called by muse, mutect2, varscan2
- MYH13 | c.2620C>A p.R874= | Silent (SNP) | VAF 109/352 reads (31%) | catalogued as COSV99351564; called by muse, mutect2, varscan2
- NEK1 | c.1374A>G p.A458= | Silent (SNP) | VAF 35/238 reads (15%) | catalogued as rs1290772384; called by muse, mutect2, varscan2
- OR9A2 | c.471T>C p.Y157= | Silent (SNP) | VAF 69/673 reads (10%) | called by muse, mutect2, varscan2
- RBM10 | c.1704C>T p.D568= | Silent (SNP) | VAF 36/299 reads (12%) | catalogued as rs781845707; called by muse, varscan2
- REXO1 | c.3282G>A p.V1094= | Silent (SNP) | VAF 34/150 reads (23%) | catalogued as COSV50081088; called by muse, mutect2, varscan2
- SLC39A1 | c.852C>G p.L284= | Silent (SNP) | VAF 114/596 reads (19%) | catalogued as rs1284839789; called by muse, mutect2, varscan2
- SOGA1 | c.3105G>C p.G1035= | Silent (SNP) | VAF 31/126 reads (25%) | called by muse, varscan2
- TBC1D30 | c.1287G>A p.T429= (on ENST00000542120; = p.T266= on NM_015279.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 65/418 reads (16%) | called by muse, mutect2, varscan2
- USH2A | c.10554C>T p.V3518= | Silent (SNP) | VAF 78/949 reads (8%) | catalogued as rs1485868763; called by muse, mutect2
- USP13 | c.1677C>T p.S559= | Silent (SNP) | VAF 101/396 reads (26%) | called by muse, mutect2, varscan2
- WDFY4 | c.1491C>T p.D497= | Silent (SNP) | VAF 55/544 reads (10%) | called by muse, mutect2
- AACS | c.358+1700C>G | Intron (SNP) | VAF 31/250 reads (12%) | called by muse, mutect2, varscan2
- ARPP19P1 | n.145T>G | RNA (SNP) | VAF 142/684 reads (21%) | called by muse, mutect2, varscan2
- CBLIF | c.79+87A>T | Intron (SNP) | VAF 78/954 reads (8%) | called by muse, mutect2
- CCDC198 | c.656-3841A>C | Intron (SNP) | VAF 13/126 reads (10%) | called by muse, mutect2
- CHRND | c.*226C>T | 3'UTR (SNP) | VAF 8/39 reads (21%) | catalogued as rs916036578; called by muse, mutect2, varscan2
- COQ5 | c.203-1596C>T | Intron (SNP) | VAF 37/193 reads (19%) | called by muse, mutect2, varscan2
- EGLN2 | chr19:40810260 T>C | 3'Flank (SNP) | VAF 52/530 reads (10%) | catalogued as rs1410332828; called by muse, mutect2
- GLYCTK | c.*177C>A | 3'UTR (SNP) | VAF 16/223 reads (7%) | called by muse, mutect2
- HSD17B7P2 | n.669C>T | RNA (SNP) | VAF 87/595 reads (15%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.3707C>A | RNA (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2
- SLC2A1 | c.18+6293C>T | Intron (SNP) | VAF 37/773 reads (5%) | catalogued as rs750346106; called by muse, mutect2
- SNED1 | c.3817+23C>T | Intron (SNP) | VAF 20/133 reads (15%) | catalogued as COSV60024891; called by mutect2, varscan2
- TCFL5 | c.1381-3617C>G | Intron (SNP) | VAF 18/447 reads (4%) | called by muse, mutect2
